Somatic mutation profile of tumor specimen TCGA-CZ-5455-01A (aliquot TCGA-CZ-5455-01A-01D-1501-10) from TCGA case TCGA-CZ-5455, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 63.4 years (23,150 days).
Specimen TCGA-CZ-5455-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1995be1-6df5-46b0-a627-2ca17009d4cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5455-11A (Solid Tissue Normal), aliquot TCGA-CZ-5455-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f03b3a88-1544-4ba0-bf85-8d8c134f0589

The open-access MAF lists 39 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 26, Silent 9, Nonsense Mutation 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PBRM1 | c.2761C>T p.R921* | Nonsense Mutation (SNP) | VAF 78/320 reads (24%) | hotspot (GDC flag); catalogued as COSV56262126; called by muse, mutect2, varscan2
- ARRDC1 | c.1230C>A p.Y410* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100604439; called by muse, mutect2, varscan2
- ATP7A | c.1403A>T p.N468I | Missense Mutation (SNP) | VAF 83/163 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV58447073; called by muse, mutect2, varscan2
- CAVIN1 | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63812258, COSV63812843; called by muse, varscan2
- CORO1B | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755458891, COSV57055405; called by muse, mutect2, varscan2
- CR2 | c.2877C>A p.H959Q | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as COSV65509855; called by muse, mutect2, varscan2
- CRYBG2 | c.4717G>A p.D1573N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as rs189284478, COSV57490620; called by muse, mutect2, varscan2
- ERMN | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 118/380 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as COSV68075859; called by muse, mutect2, varscan2
- FASTKD5 | c.1919G>T p.G640V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV99418733; called by muse, mutect2, varscan2
- FBN1 | c.6728G>A p.R2243K | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.963); catalogued as rs769589759, COSV57331771; called by muse, mutect2, varscan2
- GSAP | c.1622A>C p.H541P | Missense Mutation (SNP) | VAF 83/355 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV57533537; called by muse, mutect2, varscan2
- HOOK3 | c.1394A>G p.E465G | Missense Mutation (SNP) | VAF 58/270 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV56888348; called by muse, mutect2, varscan2
- ITGB4 | c.4903G>A p.A1635T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs914721765, COSV52333480; called by muse, mutect2, varscan2
- MON2 | c.857A>G p.N286S | Missense Mutation (SNP) | VAF 24/522 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.599); catalogued as COSV99743986; called by muse, mutect2
- MYBPHL | c.766G>C p.D256H | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV64063181; called by muse, mutect2, varscan2
- OR5A2 | c.287T>C p.V96A | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV57392022; called by muse, mutect2, varscan2
- PDCD2 | c.607A>G p.M203V | Missense Mutation (SNP) | VAF 131/537 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51341519; called by muse, mutect2, varscan2
- PEBP4 | c.197A>G p.N66S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV56472554; called by muse, mutect2, varscan2
- PHB2 | c.760A>G p.I254V | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV99781364; called by muse, mutect2, varscan2
- PON3 | c.835A>G p.I279V | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV55701879; called by muse, mutect2
- POTEE | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs1264507860, COSV100389353; called by muse, mutect2, varscan2
- PRDM1 | c.1645C>A p.L549I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV100959043, COSV64846326; called by muse, varscan2
- SLC22A4 | c.845G>C p.R282P | Missense Mutation (SNP) | VAF 58/330 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52357065, COSV52359923, COSV52360520; called by muse, mutect2, varscan2
- SLC23A1 | c.307C>A p.R103= | Splice Region (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100812139; called by muse, mutect2
- SPOCD1 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.67); catalogued as COSV99930459; called by muse, mutect2, varscan2
- SYNE2 | c.11727C>G p.I3909M | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.053); catalogued as COSV59971916; called by muse, mutect2, varscan2
- TENM3 | c.6425A>T p.Y2142F | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.347); catalogued as COSV69320590; called by muse, mutect2, varscan2
- TOMM40 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.508); catalogued as COSV99375204; called by muse, mutect2
- UBE2D1 | c.436G>C p.A146P | Missense Mutation (SNP) | VAF 127/493 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV64219009; called by muse, mutect2, varscan2
- ADCY10 | c.1878del p.F626Lfs*2 | Frame Shift Del (DEL) | VAF 104/457 reads (23%) | called by mutect2, pindel, varscan2
- ANK3 | c.4788T>A p.S1596= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV55084259; called by muse, mutect2, varscan2
- CHCHD3 | c.678A>T p.G226= | Silent (SNP) | VAF 160/661 reads (24%) | catalogued as COSV52784031; called by muse, mutect2, varscan2
- LIPG | c.480C>T p.L160= | Silent (SNP) | VAF 27/124 reads (22%) | catalogued as rs772490746, COSV54298498; called by muse, mutect2, varscan2
- MYLK4 | c.300C>A p.V100= | Silent (SNP) | VAF 75/348 reads (22%) | catalogued as COSV51142588, COSV51153738; called by muse, mutect2, varscan2
- PCDHGB2 | c.2040G>A p.E680= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs1354338158, COSV54042489; called by muse, mutect2, varscan2
- RBPJL | c.1419C>T p.F473= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100643577; called by muse, mutect2
- TRIM37 | c.2790C>T p.V930= | Silent (SNP) | VAF 40/144 reads (28%) | catalogued as COSV51885966, COSV51889119; called by muse, mutect2, varscan2
- VSIG10 | c.1488G>A p.K496= | Silent (SNP) | VAF 138/546 reads (25%) | catalogued as COSV63654567; called by muse, mutect2, varscan2
- XPO5 | c.3360A>G p.E1120= | Silent (SNP) | VAF 78/351 reads (22%) | catalogued as COSV54835749; called by muse, mutect2, varscan2
